Somatic mutation profile of tumor specimen MP2PRT-PANUKF-TMP1-A (aliquot MP2PRT-PANUKF-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANUKF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,351 days).
Specimen MP2PRT-PANUKF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5288fac5-be7a-4ee0-82df-ce55710f4f00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANUKF-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANUKF-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e403d62-b5cb-4bce-b8bc-1c81ae917b88

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Nonsense Mutation 2, Intron 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 23/516 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55937655; called by muse, mutect2
- BAZ1A | c.1421T>C p.L474P | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62411555; called by muse, mutect2
- C1orf94 | c.679C>T p.R227C (on ENST00000488417 / NM_001134734.2; = p.R37C on NM_032884.5) | Missense Mutation (SNP) | VAF 76/353 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as rs1472847493, COSV64913805; called by muse, mutect2, varscan2
- COL27A1 | c.5189C>T p.T1730M | Missense Mutation (SNP) | VAF 33/357 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769674237; called by muse, mutect2
- DACT2 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 249/616 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs761233827; called by muse, mutect2, varscan2
- EMC2 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 84/197 reads (43%) | catalogued as COSV104378013; called by muse, mutect2, varscan2
- ETV1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 165/398 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs772105404, COSV54136587; called by muse, mutect2, varscan2
- GRIN2A | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 139/369 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746978701, COSV58019618; called by muse, mutect2, varscan2
- NCOA6 | c.5141C>T p.P1714L | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs570655118, COSV62861369; called by muse, mutect2, varscan2
- OR2AK2 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV63554575; called by muse, mutect2
- PYGO1 | c.824A>T p.N275I | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs949944347, COSV57348689; called by muse, mutect2
- TMEM132E | c.1036C>T p.R346W (on ENST00000321639; = p.R436W on NM_001304438.2) | Missense Mutation (SNP) | VAF 132/317 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs141962331; called by muse, mutect2, varscan2
- TPTE | c.1571G>A p.R524Q (on ENST00000618007 / NM_199261.4; = p.R506Q on NM_199259.4) | Missense Mutation (SNP) | VAF 58/865 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs749565759; called by muse, mutect2
- WNT7A | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 49/416 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.06); catalogued as rs772783463; called by muse, mutect2, varscan2
- ZBED1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 138/772 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs752626565, COSV58133913; called by muse, mutect2, varscan2
- ACAN | c.4987G>T p.D1663Y | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- C8orf88 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 15/320 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- DHX32 | c.1515A>C p.E505D | Missense Mutation (SNP) | VAF 12/345 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- FAM135A | c.838G>C p.E280Q (on ENST00000370479 / NM_001351599.1; = p.E263Q on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2
- FLG | c.7565A>T p.Q2522L | Missense Mutation (SNP) | VAF 83/559 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- GLT6D1 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- IL31RA | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- NHLRC2 | c.2120_2125delinsCT p.L707Sfs*2 | Frame Shift Del (DEL) | VAF 136/331 reads (41%) | called by mutect2*, pindel, varscan2*
- PPP1R9A | c.386C>G p.T129S | Missense Mutation (SNP) | VAF 16/399 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.283); called by muse, mutect2
- RRP12 | c.2623_2624del p.K875Efs*57 | Frame Shift Del (DEL) | VAF 34/287 reads (12%) | called by pindel*, varscan2
- SLC24A3 | c.1526A>C p.D509A | Missense Mutation (SNP) | VAF 157/326 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VPS33B | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 117/262 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZFYVE9 | c.3667G>T p.E1223* | Nonsense Mutation (SNP) | VAF 15/291 reads (5%) | called by muse, mutect2
- ZNF546 | c.1454C>A p.T485N | Missense Mutation (SNP) | VAF 190/391 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ABCA2 | c.1545C>T p.N515= (on ENST00000614293; = p.N485= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/303 reads (18%) | catalogued as rs760098450; called by muse, mutect2, varscan2
- PRMT6 | c.813G>A p.V271= | Silent (SNP) | VAF 23/665 reads (3%) | called by muse, mutect2
- PYROXD2 | c.1539C>T p.F513= | Silent (SNP) | VAF 95/249 reads (38%) | catalogued as rs199838422, COSV65331253; called by muse, mutect2, varscan2
- RTP2 | c.297C>T p.C99= | Silent (SNP) | VAF 34/572 reads (6%) | catalogued as rs138113784; called by muse, mutect2
- SFRP4 | c.924C>A p.T308= | Silent (SNP) | VAF 48/494 reads (10%) | catalogued as rs1234877495, COSV71412251; called by muse, mutect2
- ZNF334 | c.933C>T p.H311= | Silent (SNP) | VAF 34/442 reads (8%) | catalogued as rs1488639558; called by muse, mutect2
- ITGAV | c.186-1642G>T | Intron (SNP) | VAF 143/338 reads (42%) | called by mutect2, varscan2
- WDR49 | c.-65-22784A>G | Intron (SNP) | VAF 33/329 reads (10%) | called by muse, mutect2
